Gene-level copy-number profile of tumor specimen TCGA-X6-A8C6-01A from TCGA case TCGA-X6-A8C6, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 55.0 years (20,090 days).
Specimen TCGA-X6-A8C6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.5039fe19-41b3-4aad-ab4d-084a539fde58.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X6-A8C6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40bac296-4a92-4240-b9ee-4191dd9e13bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 203; copy number 1: 20,663; copy number 2: 23,448; copy number 3: 11,896; copy number 4: 1,686; copy number 5: 879; copy number 6: 397; copy number 7: 43; copy number 8: 144; copy number 9: 107; copy number 10: 333; copy number 11: 1; copy number 12: 2; copy number 13: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X6-A8C6-01A-11D-A36I-01): tumor purity 0.35, ploidy 5.37, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 190 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:52,336,361–55,839,184, 37 genes (within-gene range 0–1): AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459, TCF4, TCF4-AS1, MIR4529, TCF4-AS2, AC022031.2, RPL21P126, LINC01415, AC022031.1.
- chr18:56,137,573–66,069,647, 153 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,815 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:75,786,197–76,779,267, 14 genes, copy number 10: RABGGTB, SNORD45C, SNORD45A, SNORD45B, MSH4, ASB17, AC092813.1, AC092813.2, ST6GALNAC3, AC103592.1, AC104458.1, TPI1P1, RNU6-161P, LINC02567.
- chr1:87,620,803–93,027,506, 105 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:146,017,468–149,936,879, 139 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:151,279,678–152,196,699, 56 genes, copy number 10 (within-gene range 2–10): ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN.
- chr1:171,485,551–172,611,833, 24 genes, copy number 10 (within-gene range 2–10): PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO.
- chr1:197,504,748–197,775,696, 6 genes, copy number 9 (within-gene range 4–9): DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1.
- chr3:83,924,157–84,051,419, 3 genes, copy number 5: AC092825.1, SRRM1P2, AC117464.1.
- chr3:163,109,152–163,361,563, 1 gene, copy number 10 (within-gene range 2–10): LINC01192.
- chr3:163,455,568–164,171,556, 4 genes, copy number 10: AC079910.1, RNU7-82P, AC084017.1, MIR1263.
- chr3:165,186,720–165,846,519, 3 genes, copy number 8: SLITRK3, LINC01322, BCHE.
- chr3:168,666,559–169,038,416, 6 genes, copy number 9: RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr6:3,585,101–5,260,950, 46 genes, copy number 10: AL033523.1, AL033523.2, PXDC1, AL391422.4, AL391422.1, AL391422.3, AL391422.2, FAM50B, AL590004.3, AL590004.2, AL590004.1, TDGF1P4, GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1, AL162718.1, AL159166.1, AL162718.3, RNA5SP202, AL162718.2, LINC02533, AL133393.1, AL034376.1, KU-MEL-3, PSMC1P11, CDYL, AL356747.1, CDYL-AS1, AL359643.1, RPP40, LYRM4-AS1, AL359643.2, AL139094.1, AL035653.1, PPP1R3G, LYRM4, MIR3691.
- chr6:5,291,030–5,291,388, 1 gene, copy number 10: AL121978.1.
- chr7:81,335,106–96,859,618, 183 genes, copy number 5 (broad region; genes not listed).
- chr8:6,406,596–6,648,508, 1 gene, copy number 6 (within-gene range 4–6): MCPH1.
- chr8:6,499,632–6,708,224, 5 genes, copy number 6 (within-gene range 4–6): ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055.
- chr8:26,254,883–27,589,073, 26 genes, copy number 6: AC079097.1, PPP2R2A, SDAD1P1, BNIP3L, AC011726.1, DNAJB6P2, AC011726.2, PNMA2, DPYSL2, PSME2P5, ADRA1A, AC091675.1, COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842, CHRNA2, EPHX2, GULOP.
- chr8:29,527,312–34,874,633, 92 genes, copy number 5–6 (broad region; genes not listed).
- chr9:68,328,308–68,531,061, 1 gene, copy number 6 (within-gene range 3–6): PGM5.
- chr9:68,393,881–71,446,904, 41 genes, copy number 6 (within-gene range 3–6): AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA, KLF9, TRPM3, RN7SL726P, AL159990.2, AL159990.1, MIR204, PIGUP1.
- chr9:71,804,283–89,498,130, 239 genes, copy number 5–13 (broad region; genes not listed).
- chr9:99,284,022–108,934,328, 134 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:18,080,869–21,176,895, 38 genes, copy number 5–8 (within-gene range 3–8): RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1.
- chr12:30,169,881–32,107,528, 64 genes, copy number 5 (broad region; genes not listed).
- chr12:32,109,076–32,109,602, 1 gene, copy number 5: AC048344.4.
- chr14:43,990,539–46,651,781, 34 genes, copy number 10: LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L.
- chr14:47,760,995–50,416,461, 57 genes, copy number 8–12 (within-gene range 2–12): MIR548Y, LINC00648, AL121576.1, AL359212.1, AL512358.1, AL512358.2, AL358335.3, RNU6-297P, AL358335.2, AL358335.1, RPL18P1, AL512360.1, AL110505.1, ATP5MC2P2, RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1.
- chr14:55,896,443–55,962,970, 1 gene, copy number 9 (within-gene range 4–9): AL163952.1.
- chr14:71,320,449–71,741,229, 1 gene, copy number 5 (within-gene range 3–5): SIPA1L1.
- chr14:71,398,337–71,590,354, 3 genes, copy number 5: SNORD56B, RN7SL683P, AC004974.1.
- chr14:73,275,107–78,060,278, 166 genes, copy number 9–10 (within-gene range 3–10) (broad region; genes not listed).
- chr14:78,177,803–78,283,376, 3 genes, copy number 9: RNA5SP388, RPS26P48, AF099810.1.
- chr15:33,310,962–33,866,121, 2 genes, copy number 5 (within-gene range 3–5): RYR3, Y_RNA.
- chr20:47,904,348–50,192,668, 61 genes, copy number 6 (broad region; genes not listed).
- chr20:50,888,916–54,269,542, 53 genes, copy number 6: ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.
- chr20:54,859,688–55,684,915, 5 genes, copy number 6 (within-gene range 4–6): RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1.
- chr20:57,488,392–57,960,176, 9 genes, copy number 5: HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1.
- chr20:58,309,715–59,325,992, 34 genes, copy number 6: RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3.
- chr20:60,087,826–64,313,132, 153 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,662. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
